Somatic mutation profile of tumor specimen TCGA-ZS-A9CF-02A (aliquot TCGA-ZS-A9CF-02A-11D-A382-10) from TCGA case TCGA-ZS-A9CF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 64.4 years (23,510 days).
Specimen TCGA-ZS-A9CF-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 143ae62c-10e2-488f-930c-3e2bdb8eb2a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZS-A9CF-10A (Blood Derived Normal), aliquot TCGA-ZS-A9CF-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d420cf66-b905-45c9-a4e5-569a5a479fdd

The open-access MAF lists 144 somatic variants for this specimen: 105 protein-altering or splice-affecting, 34 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 34, Nonsense Mutation 9, Frame Shift Del 4, Splice Site 3, Intron 2, Splice Region 2, Frame Shift Ins 2, 3'UTR 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.380A>T p.Y127F (on ENST00000326724 / NM_001080395.3; = p.Y24F on NM_004920.2) | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100452807; called by muse, mutect2, varscan2
- ABCA7 | c.5615G>T p.C1872F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1391686200, COSV99565852; called by muse, mutect2, varscan2
- AFP | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.446); catalogued as COSV99889782, COSV99890019; called by muse, mutect2, varscan2
- ATAD1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100058219; called by muse, mutect2, varscan2
- ATF6B | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs762016658, COSV100916827; called by muse, mutect2, varscan2
- ATXN3 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV100515339; called by muse, mutect2, varscan2
- B3GALT4 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV101005637; called by muse, mutect2, varscan2
- BMX | c.597del p.N201Tfs*13 | Frame Shift Del (DEL) | VAF 191/290 reads (66%) | catalogued as COSV100564652, COSV59593880; called by mutect2, pindel, varscan2
- CACNG8 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 39/49 reads (80%) | catalogued as COSV99555008; called by muse, mutect2, varscan2
- CCDC71 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1316011956, COSV100422362; called by muse, mutect2
- CD300LB | c.317T>C p.I106T | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1352775812, COSV100075436; called by muse, mutect2, varscan2
- CNBD2 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs745724867, COSV100839104; called by muse, mutect2, varscan2
- COL4A1 | c.4733G>A p.W1578* | Nonsense Mutation (SNP) | VAF 73/149 reads (49%) | catalogued as COSV101011194; called by muse, mutect2, varscan2
- CPNE4 | c.1258G>T p.V420F | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101456704; called by muse, mutect2, varscan2
- CUBN | c.159T>A p.F53L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV100910592; called by muse, mutect2, varscan2
- DGKA | c.376A>G p.R126G | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1200276920, COSV100093094; called by muse, mutect2, varscan2
- DRP2 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs369730985, COSV100871921; called by muse, mutect2, varscan2
- DRP2 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV100871922, COSV104425958; called by muse, mutect2, varscan2
- EHMT1 | c.3874G>T p.A1292S | Missense Mutation (SNP) | VAF 79/325 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV101135045; called by muse, mutect2, varscan2
- ELF5 | c.79T>C p.C27R (on ENST00000312319 / NM_198381.2; = p.C17R on NM_001422.4) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs1287219257, COSV99141209; called by muse, mutect2, varscan2
- EPG5 | c.2565C>G p.Y855* | Nonsense Mutation (SNP) | VAF 74/138 reads (54%) | catalogued as COSV99957313; called by muse, mutect2, varscan2
- EVPL | c.4759C>G p.Q1587E | Missense Mutation (SNP) | VAF 85/189 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100044589; called by muse, mutect2, varscan2
- F13A1 | c.1115A>C p.N372T | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99343086; called by muse, mutect2, varscan2
- F5 | c.1239G>T p.M413I | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100889116; called by muse, mutect2, varscan2
- FAM47B | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 74/79 reads (94%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs781613588, COSV100264354; called by muse, mutect2, varscan2
- FAM53C | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 59/274 reads (22%) | catalogued as COSV53510716; called by muse, mutect2, varscan2
- FBN3 | c.6796G>C p.G2266R | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765414073, COSV99559791; called by muse, mutect2, varscan2
- FBXO38 | c.2809A>T p.I937F (on ENST00000340253 / NM_205836.3; = p.I862F on NM_030793.5) | Missense Mutation (SNP) | VAF 76/89 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99693473; called by muse, mutect2, varscan2
- FITM2 | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1255005349, COSV101202009; called by muse, mutect2, varscan2
- FMNL3 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99526362; called by muse, mutect2, varscan2
- FOXD4L3 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100731009; called by muse, mutect2, varscan2
- FREM2 | c.5641G>T p.E1881* | Nonsense Mutation (SNP) | VAF 59/173 reads (34%) | catalogued as COSV99748920; called by muse, mutect2, varscan2
- GAA | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs377126280; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GRIA1 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 135/294 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53597752; called by muse, mutect2, varscan2
- HERC1 | c.7601T>A p.I2534K | Missense Mutation (SNP) | VAF 80/150 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV101496590; called by muse, mutect2, varscan2
- HTR3C | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV100570632; called by muse, mutect2, varscan2
- INAVA | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.635); catalogued as rs1411235480, COSV100950007; called by muse, mutect2, varscan2
- IRAK1BP1 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 227/313 reads (73%) | catalogued as COSV100884877; called by muse, mutect2, varscan2
- IVD | c.953A>C p.K318T (on ENST00000651168; = p.K315T on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV99991482; called by muse, mutect2, varscan2
- KCNA4 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs970020205, COSV100068963; called by muse, mutect2, varscan2
- KCNA5 | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.084); catalogued as COSV99363922; called by muse, mutect2, varscan2
- KIF19 | c.2090C>G p.A697G | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100739076; called by muse, mutect2
- KRT6A | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 145/323 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs749357737, COSV58108441; called by muse, mutect2, varscan2
- LCT | c.2140A>T p.N714Y | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV99929561; called by muse, mutect2, varscan2
- LGALS9 | c.1002G>T p.R334S (on ENST00000395473 / NM_009587.3; = p.R302S on NM_002308.4) | Missense Mutation (SNP) | VAF 339/818 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV100119463; called by muse, mutect2, varscan2
- MCC | c.561G>C p.E187D | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1242104729, COSV100202639; called by muse, mutect2, varscan2
- MED12L | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 82/154 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV99853267; called by muse, mutect2, varscan2
- METTL25 | c.293C>G p.T98S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV99942334; called by muse, mutect2, varscan2
- MRI1 | c.182T>A p.V61E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99237516; called by muse, mutect2
- MYCBPAP | c.76+2T>G p.X26_splice | Splice Site (SNP) | VAF 80/395 reads (20%) | catalogued as COSV100088320; called by muse, mutect2, varscan2
- MYH1 | c.3395C>T p.S1132F | Missense Mutation (SNP) | VAF 51/55 reads (93%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV56844884, COSV56850131; called by muse, mutect2, varscan2
- MYH2 | c.1979A>G p.N660S | Missense Mutation (SNP) | VAF 73/84 reads (87%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as rs926577766, COSV99820217; called by muse, mutect2, varscan2
- MYLK4 | c.159G>A p.E53= | Splice Region (SNP) | VAF 23/122 reads (19%) | catalogued as COSV99193799; called by muse, mutect2, varscan2
- MYOCD | c.1082C>A p.S361Y | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs750753749, COSV100590818; called by muse, mutect2, varscan2
- MYRIP | c.741A>C p.K247N | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100219263; called by muse, mutect2, varscan2
- NBR1 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 93/273 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100357847; called by muse, mutect2, varscan2
- NCALD | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV55272708, COSV99637276, COSV99637399; called by muse, mutect2, varscan2
- NCAM2 | c.1205A>T p.K402M | Missense Mutation (SNP) | VAF 118/239 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV99523173; called by muse, mutect2, varscan2
- NFATC2 | c.1070A>C p.Q357P | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV101044147; called by muse, mutect2, varscan2
- NINL | c.3691G>C p.D1231H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV99625407; called by muse, mutect2, varscan2
- NRG2 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.261); catalogued as COSV56832574, COSV99180337; called by muse, mutect2, varscan2
- NTF4 | c.308G>C p.W103S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100032263; called by muse, mutect2, varscan2
- NTRK2 | c.2189T>G p.F730C (on ENST00000323115 / NM_001369534.1; = p.F746C on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99455507; called by muse, mutect2, varscan2
- OLFM4 | c.184A>G p.S62G | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99524362; called by muse, mutect2, varscan2
- OR13C8 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100622980; called by muse, mutect2, varscan2
- OR1K1 | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs781701473, COSV99474278; called by muse, mutect2, varscan2
- OR4F4 | c.296T>A p.F99Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV100055396; called by mutect2, varscan2
- OR4M1 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100271230; called by muse, mutect2, varscan2
- OR5H14 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs917182258, COSV101454191; called by muse, mutect2, varscan2
- OR8H2 | c.368A>T p.Y123F | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100542342; called by muse, mutect2, varscan2
- PCLO | c.6760G>A p.D2254N | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.109); catalogued as rs1402428469, COSV61646063; called by muse, mutect2, varscan2
- PDE4D | c.2068G>A p.V690I (on ENST00000340635 / NM_001104631.2; = p.V554I on NM_006203.4) | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs192644692, COSV100401815, COSV57715130; called by muse, mutect2, varscan2
- PIWIL4 | c.257G>C p.C86S | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100133250; called by muse, mutect2, varscan2
- PRAME | c.1445T>G p.L482R | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101287092, COSV101287296; called by muse, mutect2, varscan2
- PRRC2A | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs1454783031, COSV100784582; called by muse, mutect2, varscan2
- RNF19A | c.1237A>C p.N413H | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV100347729; called by muse, mutect2, varscan2
- RORA | c.197-2A>T p.X66_splice (on ENST00000335670 / NM_134261.3; = p.X91_splice on NM_002943.3) | Splice Site (SNP) | VAF 92/188 reads (49%) | catalogued as COSV99832716; called by muse, mutect2, varscan2
- SCAP | c.2692C>T p.R898W | Missense Mutation (SNP) | VAF 105/216 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs997089172, COSV99650601; called by muse, mutect2, varscan2
- SERPINA7 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 68/80 reads (85%) | catalogued as COSV100568331; called by muse, mutect2, varscan2
- SERTAD4 | c.554A>T p.K185M | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs1264607803, COSV100882623; called by muse, mutect2, varscan2
- SF3B4 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as COSV99641187; called by muse, mutect2, varscan2
- SGK3 | c.1360A>G p.T454A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100616713; called by muse, mutect2, varscan2
- SLC22A8 | c.1594C>G p.L532V | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV100267904, COSV60324272; called by muse, mutect2, varscan2
- SLC27A1 | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1485558386, COSV99393342; called by muse, mutect2, varscan2
- SMYD3 | c.230A>G p.K77R (on ENST00000490107 / NM_001375962.1; = p.K18R on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.08); catalogued as COSV101194042; called by muse, mutect2, varscan2
- SPRY2 | c.600del p.C201Afs*12 | Frame Shift Del (DEL) | VAF 53/124 reads (43%) | catalogued as COSV101001657; called by mutect2, pindel, varscan2
- SYNE1 | c.4173T>G p.S1391R (on ENST00000367255 / NM_182961.4; = p.S1398R on NM_033071.3) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99565341; called by muse, mutect2, varscan2
- SYNJ1 | c.3218C>T p.S1073L | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs1301819492, COSV100449329; called by muse, mutect2, varscan2
- TFAP4 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs757965906, COSV99200058; called by muse, mutect2, varscan2
- TNNI2 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762215990, COSV53288930; called by muse, mutect2, varscan2
- TRERF1 | c.2667G>C p.K889N | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs752855299, COSV100550795; called by muse, mutect2, varscan2
- TRMT13 | c.325G>C p.V109L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as rs1453054588, COSV100924015; called by muse, mutect2, varscan2
- UBR3 | c.5277G>C p.Q1759H | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99774142; called by muse, mutect2, varscan2
- UGT2B7 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV100535207; called by muse, mutect2, varscan2
- UMODL1 | c.3674G>T p.G1225V (on ENST00000408910 / NM_001004416.2; = p.G1353V on NM_173568.3) | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV101252579, COSV68571312; called by muse, mutect2, varscan2
- VARS1 | c.786G>C p.E262D | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.339); catalogued as COSV100989934; called by muse, mutect2, varscan2
- ZFPM2 | c.40C>A p.R14= | Splice Region (SNP) | VAF 146/302 reads (48%) | catalogued as COSV101342977, COSV101343243; called by muse, mutect2, varscan2
- ZFYVE26 | c.3555T>A p.F1185L | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.779); catalogued as COSV100720448; called by muse, mutect2, varscan2
- ZMYND12 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100999828; called by muse, mutect2, varscan2
- ALB | c.482+5_482+8del p.X161_splice | Splice Site (DEL) | VAF 38/83 reads (46%) | called by pindel, varscan2
- ANKRD12 | c.1186dup p.T396Nfs*14 | Frame Shift Ins (INS) | VAF 20/199 reads (10%) | called by mutect2, pindel, varscan2
- CASP3 | c.674_676delinsCG p.Q225Pfs*100 | Frame Shift Del (DEL) | VAF 89/264 reads (34%) | called by pindel, varscan2*
- GLDC | c.618_619dup p.L207Hfs*25 | Frame Shift Ins (INS) | VAF 21/91 reads (23%) | called by mutect2, pindel, varscan2
- GUCY1A1 | c.251del p.P84Qfs*6 | Frame Shift Del (DEL) | VAF 72/169 reads (43%) | called by mutect2, pindel, varscan2
- IGLV3-12 | c.143_169del p.S48_Q56del | In Frame Del (DEL) | VAF 16/126 reads (13%) | called by mutect2, pindel
- AGPS | c.6G>T p.A2= | Silent (SNP) | VAF 31/56 reads (55%) | catalogued as COSV99931345; called by muse, mutect2, varscan2
- ARID5B | c.414A>G p.G138= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV54415108, COSV99689727; called by muse, mutect2, varscan2
- ASXL1 | c.3508T>C p.L1170= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV100039370, COSV60117034; called by muse, mutect2, varscan2
- BARD1 | c.15G>T p.R5= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV99638755; called by muse, mutect2, varscan2
- BNC1 | c.2628T>C p.S876= | Silent (SNP) | VAF 61/108 reads (56%) | catalogued as COSV100597217; called by muse, mutect2, varscan2
- BPIFB6 | c.273G>A p.V91= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100848519; called by muse, mutect2, varscan2
- CEP162 | c.390G>A p.E130= | Silent (SNP) | VAF 36/37 reads (97%) | catalogued as COSV57621994; called by muse, mutect2, varscan2
- CSF1R | c.2331G>A p.R777= | Silent (SNP) | VAF 52/57 reads (91%) | catalogued as COSV53828354; called by muse, mutect2, varscan2
- DAB2IP | c.2950C>A p.R984= (on ENST00000408936; = p.R956= on NM_032552.3) | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV99405548; called by muse, mutect2, varscan2
- DRC1 | c.1266C>T p.I422= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as COSV99985403; called by muse, mutect2
- FPGS | c.36A>T p.L12= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100948820; called by muse, varscan2
- GDF2 | c.207C>T p.S69= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as rs1229631161; called by muse, mutect2, varscan2
- GNA15 | c.678G>T p.V226= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV99505230; called by muse, mutect2, varscan2
- GRB10 | c.435C>T p.L145= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV100240504; called by muse, mutect2
- KNTC1 | c.2226A>G p.R742= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV100338364; called by muse, mutect2, varscan2
- KRTAP10-2 | c.756G>A p.K252= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100553727; called by muse, mutect2, varscan2
- MEGF8 | c.48C>T p.A16= | Silent (SNP) | VAF 112/236 reads (47%) | catalogued as rs777922711, COSV99236522; called by muse, mutect2, varscan2
- MIPEP | c.729A>G p.T243= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV101193124; called by muse, mutect2, varscan2
- MYBPC1 | c.1315C>T p.L439= (on ENST00000550270 / NM_206820.2; = p.L464= on NM_002465.4) | Silent (SNP) | VAF 53/115 reads (46%) | catalogued as COSV100638027; called by muse, mutect2, varscan2
- OSBPL6 | c.546T>C p.Y182= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as COSV99507516; called by muse, mutect2, varscan2
- PAX2 | c.1038C>A p.P346= (on ENST00000428433 / NM_003987.5; = p.P323= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs1436701401, COSV100695191; called by muse, mutect2, varscan2
- PCDHB6 | c.1350C>G p.T450= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV99170156; called by muse, mutect2, varscan2
- PROM2 | c.459C>A p.A153= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV100469024; called by muse, mutect2, varscan2
- RABGAP1 | c.69A>G p.E23= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs1302726606, COSV100438589; called by muse, mutect2, varscan2
- SCN11A | c.735C>A p.A245= | Silent (SNP) | VAF 85/172 reads (49%) | catalogued as COSV56569806; called by muse, mutect2, varscan2
- SLC25A31 | c.30A>T p.A10= | Silent (SNP) | VAF 87/335 reads (26%) | catalogued as COSV99829456; called by muse, mutect2, varscan2
- SLC6A8 | c.1431G>C p.S477= | Silent (SNP) | VAF 60/64 reads (94%) | catalogued as COSV99465953; called by muse, mutect2, varscan2
- TSNAX | c.672T>C p.V224= | Silent (SNP) | VAF 145/262 reads (55%) | catalogued as COSV100791109; called by muse, mutect2, varscan2
- TTC3 | c.4764C>G p.T1588= | Silent (SNP) | VAF 84/557 reads (15%) | catalogued as rs1209135129, COSV100695570; called by muse, mutect2, varscan2
- TTN | c.44028T>A p.T14676= (on ENST00000591111; = p.T7252= on NM_003319.4) | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV100614476; called by muse, mutect2, varscan2
- WWP2 | c.2226G>A p.E742= | Silent (SNP) | VAF 14/147 reads (10%) | catalogued as COSV100598569, COSV63122400; called by muse, mutect2
- ZBTB37 | c.729A>G p.V243= | Silent (SNP) | VAF 88/242 reads (36%) | catalogued as COSV100774594; called by muse, mutect2, varscan2
- ZIM2 | c.1101C>A p.L367= | Silent (SNP) | VAF 45/46 reads (98%) | catalogued as COSV55634935, COSV55644582, COSV99689073; called by muse, mutect2, varscan2
- ZPLD1 | c.267A>G p.P89= (on ENST00000466937 / NM_001329788.1; = p.P105= on NM_175056.2) | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV100083260; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3562G>A | 3'UTR (SNP) | VAF 43/175 reads (25%) | catalogued as rs536780208, COSV100082532; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+17A>C | Intron (SNP) | VAF 18/65 reads (28%) | catalogued as COSV99180710; called by muse, mutect2, varscan2
- CHMP1A | c.*86_*112del | 3'UTR (DEL) | VAF 40/274 reads (15%) | called by pindel, varscan2
- ESRRB | c.1296+363G>A | Intron (SNP) | VAF 9/20 reads (45%) | catalogued as rs558976888, COSV99835284; called by muse, mutect2, varscan2
- UBTFL2 | n.564G>A | RNA (SNP) | VAF 54/181 reads (30%) | called by muse, mutect2, varscan2
